Somatic mutation profile of tumor specimen MBCProject_2575_T1_WES (aliquot MBCProject_2575_T1_WES_1) from CMI case MBCProject_2575, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 36.8 years (13,440 days).
Specimen MBCProject_2575_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ec2ef23-9829-4102-a459-dcaaa6ac8a83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_2575_SALIVA (Saliva), aliquot MBCProject_2575_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd7e96bb-b28e-447a-8995-35174bb66a83

The open-access MAF lists 34 somatic variants for this specimen: 21 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 10, 3'UTR 2, Intron 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRE1 | c.2520C>G p.I840M | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV51671954; called by muse, varscan2
- C7orf57 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs200433005, COSV100817309, COSV62364505; called by muse, mutect2, varscan2
- CHTF18 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs377268098; called by muse, mutect2, varscan2
- CLK1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 60/192 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as rs1414475368; called by muse, mutect2, varscan2
- DCLRE1A | c.1043A>G p.H348R | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1301471048; called by muse, mutect2, varscan2
- KCNA1 | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs1259861866; called by muse, mutect2, varscan2
- PCDHB15 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs782788911, COSV50886810; called by muse, varscan2
- PIK3CG | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs1377001952, COSV63248165; called by muse, mutect2, varscan2
- SCN4A | c.2234A>G p.H745R | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs762279435; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SP100 | c.2573_2576del p.K858Rfs*33 | Frame Shift Del (DEL) | VAF 13/80 reads (16%) | catalogued as rs752347836; called by mutect2, pindel, varscan2
- AASS | c.1605A>C p.K535N | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AC138647.1 | c.334C>A p.P112T | Missense Mutation (SNP) | VAF 81/151 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADGRE1 | c.2626C>G p.L876V | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CIAO3 | c.824-11_844del p.X275_splice | Splice Site (DEL) | VAF 30/108 reads (28%) | called by mutect2, pindel
- HMCN1 | c.6608T>A p.L2203H | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.9); called by muse, mutect2
- LONP1 | c.2448A>G p.I816M | Missense Mutation (SNP) | VAF 13/315 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MME | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- RUNX1 | c.8T>G p.I3S | Missense Mutation (SNP) | VAF 45/324 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- SEMA3D | c.138G>T p.K46N | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- TEKT5 | c.59G>A p.G20D | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TGDS | c.193T>C p.S65P | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- CCR4 | c.264C>T p.F88= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs775907855, COSV58383724; called by muse, mutect2, varscan2
- CLK1 | c.447G>A p.L149= | Silent (SNP) | VAF 50/175 reads (29%) | called by muse, varscan2
- GIMAP1 | c.324G>A p.S108= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV56188450; called by muse, mutect2
- HMGN1 | c.180A>G p.G60= | Silent (SNP) | VAF 61/234 reads (26%) | called by muse, mutect2, varscan2
- HTR1A | c.327C>T p.C109= | Silent (SNP) | VAF 52/351 reads (15%) | catalogued as COSV100109023; called by muse, mutect2, varscan2
- ILF3 | c.1644G>T p.G548= | Silent (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
- SKOR2 | c.2292C>T p.D764= | Silent (SNP) | VAF 15/46 reads (33%) | called by muse, varscan2
- TCF4 | c.1452C>T p.S484= | Silent (SNP) | VAF 68/217 reads (31%) | called by muse, mutect2, varscan2
- USP35 | c.486G>A p.L162= | Silent (SNP) | VAF 92/1666 reads (6%) | called by muse, mutect2
- ZDHHC9 | c.66C>T p.T22= | Silent (SNP) | VAF 44/71 reads (62%) | catalogued as rs1435350571; called by muse, mutect2, varscan2
- ADGRE1 | c.*4C>T | 3'UTR (SNP) | VAF 42/181 reads (23%) | catalogued as rs752806916; called by muse, varscan2
- PADI4 | c.340+485A>G | Intron (SNP) | VAF 4/26 reads (15%) | catalogued as rs1036598090; called by muse, varscan2
- SERF2 | c.*132A>G | 3'UTR (SNP) | VAF 44/117 reads (38%) | called by muse, mutect2, varscan2
